Somatic mutation profile of tumor specimen TCGA-CV-6961-01A (aliquot TCGA-CV-6961-01A-21D-1912-08) from TCGA case TCGA-CV-6961, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.7 years (22,532 days).
Specimen TCGA-CV-6961-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0609c0b-f93e-4ba8-bfe4-0cce59f3f066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6961-10A (Blood Derived Normal), aliquot TCGA-CV-6961-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e34f189b-d548-4afd-81c7-e89e44b507a3

The open-access MAF lists 612 somatic variants for this specimen: 431 protein-altering or splice-affecting, 154 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 382, Silent 154, Nonsense Mutation 35, Intron 12, 5'Flank 8, Splice Region 5, Splice Site 3, 5'UTR 2, 3'Flank 2, RNA 2, Frame Shift Ins 2, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HAX1 | c.383C>G p.S128* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as rs1398108109, COSV99671935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913315, CM991156, COSV58820621, COSV58820976, COSV99045288; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABAT | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as rs764665721, COSV51629662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA2 | c.3340G>A p.E1114K (on ENST00000614293; = p.E1084K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55808072; called by muse, varscan2
- ABCA2 | c.3274G>A p.E1092K (on ENST00000614293; = p.E1062K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV99688177; called by muse, varscan2
- ABCA2 | c.1846G>A p.E616K (on ENST00000614293; = p.E586K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772804718, COSV99688178; called by muse, mutect2, varscan2
- ACIN1 | c.2072G>C p.C691S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs751078664, COSV99400111; called by muse, mutect2, varscan2
- ACIN1 | c.966G>C p.E322D | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); catalogued as COSV52975377; called by muse, mutect2, varscan2
- ADAMTS14 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100941771; called by muse, mutect2
- ADAMTS3 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54385585; called by muse, mutect2, varscan2
- ADAMTS6 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs933525732; called by muse, mutect2, varscan2
- ADAP1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.251); catalogued as rs1232440867, COSV99763181, COSV99763279; called by muse, mutect2, varscan2
- ADGRV1 | c.12712C>T p.Q4238* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV101316294; called by muse, mutect2, varscan2
- AFM | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs867156410, COSV99889048; called by muse, mutect2, varscan2
- AGL | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99649838; called by muse, mutect2, varscan2
- AGL | c.3415C>G p.L1139V | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99649841; called by muse, mutect2, varscan2
- AHDC1 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1557663014, COSV55940173; called by muse, mutect2, varscan2
- AHRR | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs368948224; called by mutect2, varscan2
- AHSG | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99890097, COSV99890236; called by muse, mutect2, varscan2
- AIP | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99653779; called by muse, mutect2
- AKAP13 | c.787C>G p.H263D | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100774276, COSV63451253; called by muse, mutect2, varscan2
- AKAP3 | c.1292G>C p.R431T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs867725078, COSV99962481; called by muse, mutect2, varscan2
- AKAP4 | c.857T>C p.M286T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.085); catalogued as COSV100654325; called by muse, mutect2, varscan2
- AKR7L | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101334360; called by muse, mutect2, varscan2
- ALDH16A1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs768824851, COSV99513122; called by muse, varscan2
- ALDH1L1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV99857286; called by muse, mutect2, varscan2
- ALKBH3 | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100236069; called by muse, mutect2, varscan2
- ALPI | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746696173, COSV55013774; called by muse, mutect2, varscan2
- ALPK3 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99361676; called by muse, mutect2, varscan2
- ALPK3 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99361677; called by muse, mutect2, varscan2
- ANKRD17 | c.5641C>T p.L1881F | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV58215449; called by muse, mutect2, varscan2
- ANKZF1 | c.1619A>T p.H540L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99850782; called by muse, mutect2, varscan2
- APOB | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs754723900, COSV51948739; called by muse, mutect2, varscan2
- ARCN1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99873869; called by muse, mutect2, varscan2
- ARHGEF40 | c.4450C>A p.Q1484K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100070575; called by muse, mutect2, varscan2
- ARID2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100536700, COSV57609648; called by muse, mutect2, varscan2
- ARID4B | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99936081; called by muse, mutect2
- ARRDC3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs371971226; called by muse, mutect2, varscan2
- ATP13A3 | c.2398C>T p.H800Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV99757471; called by muse, mutect2, varscan2
- ATP13A4 | c.1011G>C p.Q337H | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55072085, COSV99795048; called by muse, mutect2, varscan2
- B4GALNT3 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV99843409; called by muse, mutect2, varscan2
- BACH2 | c.1881G>T p.R627S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100000478; called by muse, mutect2, varscan2
- BBS4 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs748048479, COSV99166508; called by muse, mutect2, varscan2
- BCAN | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV100228349; called by muse, mutect2
- BCKDK | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV54893059; called by muse, mutect2, varscan2
- BEST3 | c.1242G>C p.R414S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100437915; called by muse, varscan2
- BICD2 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100794229; called by muse, mutect2
- BID | c.710G>A p.R237K (on ENST00000317361 / NM_197966.2; = p.R191K on NM_001196.4) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV58006095; called by muse, mutect2, varscan2
- BIN3 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs1563958882, COSV99374242; called by muse, mutect2, varscan2
- BLOC1S3 | c.528C>G p.I176M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99135349; called by muse, mutect2
- BMPR2 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV101001605; called by muse, mutect2, varscan2
- BMX | c.1403G>T p.S468I | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100564595; called by muse, mutect2, varscan2
- BRD9 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV60246649; called by muse, mutect2, varscan2
- BTBD6 | c.1034C>A p.A345D | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV100527605; called by muse, mutect2, varscan2
- C19orf57 | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100694798; called by muse, mutect2, varscan2
- C20orf194 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.242); catalogued as COSV99331274; called by muse, mutect2, varscan2
- C4orf45 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101465149; called by muse, mutect2, varscan2
- CACNA1G | c.4408G>C p.D1470H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100662311; called by muse, mutect2, varscan2
- CACNA1G | c.4451C>G p.S1484C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as COSV100662314; called by muse, mutect2, varscan2
- CACNA2D1 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100667036; called by muse, mutect2, varscan2
- CACNG4 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs370622371; called by muse, mutect2, varscan2
- CBX7 | c.455C>G p.S152W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53358886, COSV99334154; called by muse, mutect2
- CCDC191 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99878599; called by muse, mutect2, varscan2
- CCDC32 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100785991; called by muse, mutect2, varscan2
- CCDC34 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV58725747, COSV58726475; called by muse, mutect2, varscan2
- CCDC9 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.539); catalogued as rs750101021, COSV55722977; called by muse, mutect2, varscan2
- CCL2 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99861506, COSV99861571; called by muse, mutect2, varscan2
- CCNT1 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV99980855; called by muse, mutect2, varscan2
- CDH13 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as COSV51794489, COSV99229022; called by muse, mutect2, varscan2
- CECR2 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99378754; called by muse, mutect2, varscan2
- CELF6 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV54716595; called by muse, mutect2, varscan2
- CELSR2 | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99604493; called by muse, mutect2, varscan2
- CEP104 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100986363; called by muse, mutect2
- CEP250 | c.582G>C p.M194I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100699093; called by muse, varscan2
- CERS3 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV99432494; called by muse, mutect2, varscan2
- CHD1L | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs368838337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA3 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100468509; called by muse, mutect2
- CIT | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99950480; called by muse, mutect2, varscan2
- CLASP1 | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99756455; called by muse, mutect2, varscan2
- CLTCL1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1555951472, COSV54230412; called by muse, mutect2, varscan2
- CMSS1 | c.228G>A p.K76= | Splice Region (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101375609; called by muse, mutect2, varscan2
- CMYA5 | c.5224C>T p.Q1742* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV101484254; called by muse, mutect2, varscan2
- COPB1 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747328759, COSV99999814; called by muse, mutect2, varscan2
- CPD | c.3898C>G p.L1300V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.664); catalogued as COSV99853155; called by muse, varscan2
- CRTC3 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.345); catalogued as COSV99185773; called by muse, mutect2, varscan2
- CYFIP1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1468511893; called by muse, mutect2, varscan2
- DCBLD2 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs994526826, COSV99505131; called by muse, mutect2, varscan2
- DHX9 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100841484; called by muse, mutect2, varscan2
- DIS3L2 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56060410, COSV99806979; called by muse, mutect2, varscan2
- DLG1 | c.2266G>A p.D756N (on ENST00000419354 / NM_001290983.1; = p.D778N on NM_004087.2) | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV58383080; called by muse, mutect2
- DLGAP4 | c.2935G>C p.D979H (on ENST00000339266 / NM_001365621.1; = p.D976H on NM_014902.6) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211489, COSV59417347; called by muse, mutect2, varscan2
- DMD | c.4701G>T p.E1567D | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100817124; called by muse, mutect2, varscan2
- DNAH17 | c.9557C>T p.A3186V | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747233018, COSV67750093; called by muse, mutect2, varscan2
- DSTYK | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100904670; called by muse, mutect2, varscan2
- DTX4 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99915818; called by muse, mutect2, varscan2
- DYM | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99493795; called by muse, varscan2
- EGFR | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.946); catalogued as COSV51786507, COSV51839851; called by muse, mutect2, varscan2
- EIF4G2 | c.50C>G p.S17W | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101151049, COSV60596497; called by muse, mutect2, varscan2
- ELMO3 | c.1888G>C p.D630H (on ENST00000652269; = p.D577H on NM_024712.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440953, COSV58527468; called by muse, mutect2, varscan2
- ENAM | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV101253275; called by muse, mutect2, varscan2
- EPCAM | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV99764264; called by muse, mutect2, varscan2
- EPPK1 | c.4111G>A p.G1371R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs376905444; called by muse, mutect2, varscan2
- ESRRA | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV99134794; called by muse, mutect2, varscan2
- ETS2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100711355; called by muse, mutect2, varscan2
- ETS2 | c.1409G>T p.*470Lext*66 | Nonstop Mutation (SNP) | VAF 34/46 reads (74%) | catalogued as COSV100711357; called by muse, mutect2, varscan2
- FAM111A | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs1208259598, COSV100659416; called by muse, mutect2, varscan2
- FAM135B | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs758410872, COSV52731787, COSV52738227, COSV99426198; called by muse, mutect2, varscan2
- FAM135B | c.1742C>G p.S581C | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52715595, COSV99426202; called by muse, mutect2, varscan2
- FAM3B | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100783762; called by muse, mutect2, varscan2
- FAM91A1 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100593724; called by muse, mutect2
- FANCA | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101225072; called by muse, mutect2, varscan2
- FASN | c.3580C>G p.L1194V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV100148147; called by muse, mutect2, varscan2
- FBN2 | c.8092G>C p.E2698Q | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99329640; called by muse, mutect2, varscan2
- FBXL13 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99978576; called by muse, mutect2, varscan2
- FCRL4 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54861201, COSV99620154; called by muse, varscan2
- FERMT3 | c.1943G>A p.R648H (on ENST00000279227 / NM_178443.3; = p.R644H on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs368565732, COSV99655976; called by muse, mutect2, varscan2
- FILIP1L | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100497216; called by muse, mutect2, varscan2
- FKBPL | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV64322478, COSV64322665; called by muse, varscan2
- FKBPL | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100913596, COSV64322675; called by muse, varscan2
- FLG | c.5029C>G p.P1677A | Missense Mutation (SNP) | VAF 139/641 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.103); catalogued as rs373806639, COSV64244325; called by muse, mutect2, varscan2
- FLG | c.3653G>C p.R1218T | Missense Mutation (SNP) | VAF 133/546 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV100911924; called by muse, mutect2, varscan2
- FLG | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 130/436 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64242203; called by mutect2, varscan2
- FLG2 | c.6892C>T p.H2298Y | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV101166079; called by muse, mutect2
- FRAS1 | c.10999C>T p.Q3667* | Nonsense Mutation (SNP) | VAF 33/159 reads (21%) | catalogued as COSV53607154, COSV99354699; called by muse, mutect2, varscan2
- FSCN3 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as rs748533837, COSV99133866; called by muse, mutect2, varscan2
- FUBP3 | c.1470C>A p.S490R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100156254; called by muse, mutect2, varscan2
- FXR1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99976588; called by muse, mutect2, varscan2
- GALNT16 | c.978C>G p.F326L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100546111; called by muse, mutect2, varscan2
- GAN | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1335651050, COSV101634022, COSV73720932; called by muse, mutect2, varscan2
- GAPVD1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99783585, COSV99783872; called by muse, mutect2, varscan2
- GATA6 | c.1303-1G>A p.X435_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as CS131446, COSV99333381; called by mutect2, varscan2
- GATAD2B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64083908; called by muse, mutect2, varscan2
- GBA2 | c.2768A>T p.N923I | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV100148076; called by muse, varscan2
- GLI1 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV99954464; called by muse, mutect2, varscan2
- GNPDA1 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as COSV100257667; called by muse, mutect2, varscan2
- GPR1 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV101329857; called by muse, mutect2, varscan2
- GREB1 | c.5096G>T p.W1699L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99303475; called by muse, mutect2, varscan2
- GRHL1 | c.1380C>G p.F460L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.39); catalogued as COSV100258055; called by muse, mutect2, varscan2
- GRIA2 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201110038, COSV99645478; called by muse, mutect2, varscan2
- GTF2E1 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99381868, COSV99382100; called by muse, mutect2, varscan2
- GTSE1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748370009, COSV101483238; called by muse, mutect2, varscan2
- HDHD3 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99445062; called by muse, mutect2, varscan2
- HENMT1 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100898633; called by muse, mutect2, varscan2
- HERC2 | c.5941C>T p.H1981Y | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99875829; called by muse, mutect2, varscan2
- HEXA | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99173808; called by muse, varscan2
- HIVEP1 | c.2746G>A p.G916R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as rs574039329, COSV65102572, COSV65104120; called by muse, mutect2, varscan2
- HIVEP2 | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99174897; called by muse, mutect2, varscan2
- HOXB7 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 31/128 reads (24%) | catalogued as COSV99494151; called by muse, mutect2, varscan2
- HOXD8 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs1417221839, COSV100497137; called by muse, mutect2, varscan2
- HRC | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53255322, COSV99418203; called by muse, mutect2, varscan2
- HRG | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1276242614, COSV99214969; called by muse, mutect2, varscan2
- HUWE1 | c.5991G>C p.Q1997H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99473576; called by muse, mutect2, varscan2
- IGF2R | c.3693C>G p.D1231E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100807925; called by muse, mutect2, varscan2
- IGHV3-23 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 56/486 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs566326210; called by muse, mutect2, varscan2
- IGSF21 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV99245767; called by muse, mutect2, varscan2
- IL10RA | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.387); catalogued as COSV99923207; called by muse, mutect2, varscan2
- IL4R | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748811310, COSV50139604; called by muse, mutect2, varscan2
- INPP1 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV100487297; called by muse, mutect2, varscan2
- INPP5D | c.2143C>A p.Q715K (on ENST00000445964 / NM_001017915.3; = p.Q714K on NM_005541.5) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100856881; called by muse, mutect2, varscan2
- IRF1 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV99810647; called by muse, mutect2, varscan2
- ITPR3 | c.6666C>G p.F2222L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967849; called by muse, mutect2, varscan2
- KATNB1 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101109966; called by muse, mutect2
- KATNIP | c.4633G>C p.E1545Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV99851708; called by muse, mutect2, varscan2
- KCNJ3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54543276; called by muse, mutect2, varscan2
- KDM5B | c.1324G>C p.D442H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV99351142; called by muse, mutect2, varscan2
- KIF27 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV99927198; called by muse, mutect2, varscan2
- KLRC3 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101122927; called by muse, mutect2, varscan2
- KPNA1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100724313; called by muse, mutect2, varscan2
- KPRP | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 13/161 reads (8%) | catalogued as COSV100908764; called by muse, mutect2
- KRT5 | c.1167G>C p.M389I | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV99358194; called by muse, mutect2, varscan2
- KRTAP10-1 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100554904; called by muse, mutect2, varscan2
- KRTAP10-1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100552560; called by muse, mutect2, varscan2
- KRTAP10-4 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs782062312, COSV100554907; called by muse, mutect2
- LAMA3 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100555596, COSV100557400, COSV58075359; called by muse, mutect2, varscan2
- LAT | c.164-1G>C p.X55_splice | Splice Site (SNP) | VAF 42/135 reads (31%) | catalogued as COSV100209207; called by muse, mutect2, varscan2
- LGALS12 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55371424; called by muse, mutect2, varscan2
- LIFR | c.3055G>C p.E1019Q | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV99665017; called by muse, mutect2, varscan2
- LIMK1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV100283361; called by muse, mutect2, varscan2
- LIMS2 | c.20C>T p.S7L (on ENST00000355119 / NM_001161403.3; = p.S31L on NM_017980.4) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs369093987; called by muse, mutect2, varscan2
- LIN54 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100464883; called by muse, mutect2
- LRBA | c.3469C>T p.Q1157* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as COSV63949497; called by muse, mutect2, varscan2
- LRRC37B | c.2646G>C p.Q882H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100496426, COSV58951890; called by muse, mutect2, varscan2
- LRRC66 | c.1374C>G p.F458L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58632876, COSV58635285; called by muse, mutect2, varscan2
- LRRIQ1 | c.2108C>G p.S703C | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV101280661; called by muse, mutect2, varscan2
- LRRIQ1 | c.3361C>T p.Q1121* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV101280662; called by muse, mutect2, varscan2
- LSM14B | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs754027553, COSV99444589; called by muse, mutect2, varscan2
- LTBR | c.1199C>G p.S400C | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99965378; called by muse, mutect2, varscan2
- LYPLAL1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 30/138 reads (22%) | catalogued as rs140122550; called by muse, varscan2
- MAGEA6 | c.944G>C p.*315Sext*2 | Nonstop Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100262935; called by muse, mutect2, varscan2
- MAN2A2 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100847951, COSV64639496; called by muse, mutect2, varscan2
- MAP10 | c.437C>G p.S146W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs768882334, COSV101406533, COSV99081438; called by muse, mutect2, varscan2
- MAP1A | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55809087; called by muse, mutect2, varscan2
- MAP1B | c.4844G>C p.R1615T | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99702781; called by muse, mutect2
- MAP1LC3C | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100606524; called by muse, mutect2, varscan2
- MAPK8IP3 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs777199250, COSV51719287; called by muse, mutect2, varscan2
- MCF2L2 | c.3127G>C p.D1043H | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV100193507, COSV61052246; called by muse, mutect2
- MCL1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV57190122; called by muse, mutect2, varscan2
- MCM2 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 74/316 reads (23%) | catalogued as COSV54033482; called by muse, mutect2, varscan2
- MCTS1 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100989176; called by muse, mutect2, varscan2
- METTL6 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs1227495752, COSV101085075; called by muse, mutect2, varscan2
- MIA2 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54482442, COSV99696873; called by muse, mutect2, varscan2
- MIB1 | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 55/196 reads (28%) | catalogued as COSV99839237; called by muse, mutect2, varscan2
- MKNK1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs757036292, COSV100361448; called by muse, mutect2, varscan2
- MLNR | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776782486, COSV99519988; called by muse, mutect2, varscan2
- MOGAT1 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV101485109, COSV101485121; called by muse, mutect2, varscan2
- MOGS | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs746113375, COSV99270343, COSV99270698; called by muse, mutect2, varscan2
- MPL | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65243896; called by muse, mutect2, varscan2
- MROH2B | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101270459, COSV101270466; called by muse, mutect2, varscan2
- MRPL47 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV99373039; called by muse, mutect2
- MTG2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV100895189; called by muse, mutect2, varscan2
- MUC16 | c.40562A>G p.N13521S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.702); catalogued as rs1372458569, COSV101110011; called by muse, mutect2, varscan2
- MUC16 | c.34418C>T p.T11473I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as rs761731420, COSV101200688; called by muse, mutect2, varscan2
- MUC4 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62206115; called by muse, mutect2, varscan2
- MYH7B | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as rs1378209037, COSV99483121; called by muse, mutect2, varscan2
- MYH9 | c.3392A>T p.E1131V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99339518; called by muse, mutect2, varscan2
- MYH9 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99338190, COSV99339520; called by muse, mutect2
- MYO7A | c.1557C>T p.G519= | Splice Region (SNP) | VAF 38/130 reads (29%) | catalogued as COSV101289228; called by muse, mutect2, varscan2
- NACA | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100771512; called by muse, varscan2
- NACA | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV63268851; called by muse, varscan2
- NACA | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV100771514; called by muse, mutect2, varscan2
- NEB | c.17230G>C p.D5744H | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426095; called by muse, mutect2, varscan2
- NEK1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101455775; called by muse, mutect2, varscan2
- NFKBIZ | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100397156; called by muse, mutect2, varscan2
- NKTR | c.3643G>C p.E1215Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV51772487; called by muse, mutect2, varscan2
- NKTR | c.3786G>C p.L1262F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV99236143; called by muse, mutect2, varscan2
- NOSTRIN | c.248C>T p.A83V (on ENST00000317647 / NM_001039724.4; = p.A5V on NM_052946.3) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772890682, COSV58322384; called by muse, mutect2, varscan2
- NPLOC4 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100481145; called by muse, mutect2, varscan2
- NPTX2 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99675038; called by muse, mutect2, varscan2
- NRAP | c.3613C>T p.R1205W (on ENST00000359988 / NM_001322945.2; = p.R1170W on NM_006175.4) | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377301664; called by muse, mutect2, varscan2
- NRROS | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.026); catalogued as COSV100145566; called by muse, mutect2, varscan2
- NSD1 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV100729671; called by muse, mutect2, varscan2
- NSUN7 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); catalogued as COSV100349529; called by muse, mutect2, varscan2
- NSUN7 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV100349530; called by muse, mutect2, varscan2
- NT5C3A | c.415G>C p.E139Q (on ENST00000610140 / NM_001374335.1; = p.E105Q on NM_016489.13) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV99641324; called by muse, mutect2, varscan2
- NUP155 | c.2889G>C p.Q963H (on ENST00000231498 / NM_153485.3; = p.Q904H on NM_004298.4) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV99194080; called by muse, mutect2, varscan2
- NUP37 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192222215, COSV51837811; called by muse, mutect2, varscan2
- NYNRIN | c.3062C>G p.S1021C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV101230653; called by muse, mutect2, varscan2
- ODAM | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV101258095, COSV68572710; called by muse, mutect2, varscan2
- OPA3 | c.357G>C p.W119C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV99620091; called by muse, mutect2, varscan2
- OR1L3 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as COSV59170636; called by muse, mutect2, varscan2
- OR2W3 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100831782; called by muse, mutect2, varscan2
- OR4D2 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.125); catalogued as COSV101613862, COSV101613867, COSV73459779; called by muse, mutect2
- OR4D9 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61434621; called by muse, mutect2, varscan2
- OR8S1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV100043420, COSV100043685; called by muse, mutect2, varscan2
- OS9 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99233005; called by muse, mutect2
- OSBPL9 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100543882; called by muse, mutect2, varscan2
- OSCP1 | c.1099G>C p.E367Q (on ENST00000356637 / NM_001330493.1; = p.E357Q on NM_145047.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV52485407; called by muse, mutect2, varscan2
- OSGEPL1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51462883, COSV99918475; called by muse, mutect2, varscan2
- OVCH1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs373419953; called by muse, mutect2, varscan2
- P3H2 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077890; called by muse, mutect2, varscan2
- P4HB | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs199956742, COSV58942596; called by muse, mutect2, varscan2
- PACSIN2 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as COSV99606560; called by muse, mutect2, varscan2
- PAPSS1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs1419573138, COSV99492298; called by muse, mutect2, varscan2
- PARP8 | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as COSV99892337; called by muse, mutect2, varscan2
- PCDH17 | c.1932G>T p.E644D | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV64972194; called by muse, mutect2, varscan2
- PCDHB15 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); catalogued as COSV50863926, COSV99179091; called by muse, mutect2
- PCDHB2 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV50564805, COSV99166067; called by muse, mutect2, varscan2
- PCDHB6 | c.470A>T p.H157L | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99170638; called by muse, mutect2, varscan2
- PCMTD2 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV99829553; called by muse, mutect2, varscan2
- PCNT | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100855876; called by muse, mutect2
- PDE3A | c.2485C>A p.L829M | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762645; called by muse, mutect2, varscan2
- PDGFRL | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1332404466, COSV52411229, COSV99286588; called by muse, mutect2, varscan2
- PGBD1 | c.276C>G p.F92L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99460702; called by muse, mutect2, varscan2
- PHF12 | c.972G>C p.L324= | Splice Region (SNP) | VAF 11/59 reads (19%) | catalogued as COSV52021577, COSV99256085; called by muse, mutect2, varscan2
- PHF23 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.429); catalogued as COSV99138722; called by muse, mutect2, varscan2
- PIN4 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99512535; called by muse, mutect2, varscan2
- PIWIL2 | c.2557C>T p.Q853* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | catalogued as COSV100769498; called by muse, mutect2, varscan2
- PLCH2 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs867099837, COSV99616276; called by muse, mutect2, varscan2
- PLEC | c.6406G>C p.E2136Q (on ENST00000322810 / NM_201380.4; = p.E2026Q on NM_000445.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV100517300; called by muse, mutect2
- PLEC | c.1987C>T p.Q663* (on ENST00000322810 / NM_201380.4; = p.Q553* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100517303; called by muse, mutect2, varscan2
- PLEKHG7 | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV100468264; called by muse, mutect2, varscan2
- PLEKHO2 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100060881; called by muse, mutect2, varscan2
- PLG | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99804220; called by muse, mutect2, varscan2
- POLE | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs768396766, COSV100267729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2J3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767362640; called by mutect2, varscan2
- PPFIBP1 | c.1921G>C p.D641H (on ENST00000318304 / NM_177444.3; = p.D635H on NM_003622.4) | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99945248; called by muse, mutect2, varscan2
- PPP1R13B | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV52450953, COSV99161187; called by muse, mutect2, varscan2
- PPP1R18 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV51294688, COSV99223833; called by muse, mutect2, varscan2
- PPP6R2 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 94/377 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99324616; called by muse, mutect2, varscan2
- PRAMEF2 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV99535509; called by muse, mutect2, varscan2
- PRDM11 | c.792G>A p.M264I (on ENST00000530656 / NM_001359633.1; = p.M230I on NM_001256695.1) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV99771008; called by muse, mutect2, varscan2
- PRKAG3 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1361972890, COSV52100688; called by muse, mutect2, varscan2
- PRRT1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99278615; called by muse, mutect2, varscan2
- PRUNE2 | c.9136G>A p.E3046K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1345790118, COSV99796238; called by muse, mutect2, varscan2
- PSMG1 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV100521921; called by muse, mutect2, varscan2
- PTPRD | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100646029, COSV61984845; called by muse, mutect2, varscan2
- RAD51AP2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV101208390; called by muse, mutect2, varscan2
- RALGDS | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1224712997, COSV64427032; called by muse, mutect2, varscan2
- RALGDS | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs367807822, COSV64428188; called by muse, mutect2, varscan2
- RAPGEF3 | c.941C>T p.A314V (on ENST00000389212; = p.A272V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV99406671; called by muse, mutect2, varscan2
- RASGRF1 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); catalogued as rs1308981599, COSV101174681; called by muse, mutect2, varscan2
- RBM27 | c.2846C>G p.S949C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs781659521, COSV99506471; called by muse, mutect2, varscan2
- RCC2 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100965185; called by muse, mutect2, varscan2
- RESF1 | c.1781C>G p.T594S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.165); catalogued as COSV100440508; called by muse, mutect2, varscan2
- RIMKLA | c.836G>C p.G279A | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101290571; called by muse, mutect2
- RIN3 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.421); catalogued as COSV99379743; called by muse, mutect2, varscan2
- RIPK1 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV99454748; called by muse, mutect2, varscan2
- RNF145 | c.1951C>T p.H651Y (on ENST00000424310 / NM_001199383.2; = p.H679Y on NM_144726.2) | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV99193796; called by muse, mutect2, varscan2
- RNF169 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100213511; called by muse, mutect2, varscan2
- RRP1B | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100513159; called by muse, mutect2
- RSPH10B | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100382910; called by muse, mutect2, varscan2
- RSPH4A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.11); catalogued as COSV57635651, COSV99994254; called by muse, mutect2, varscan2
- RSRC1 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1482922124, COSV55822592; called by muse, mutect2
- RUBCN | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99584743; called by muse, mutect2, varscan2
- RUSC1 | c.1812C>T p.L604= (on ENST00000368352 / NM_001105203.2; = p.L135= on NM_014328.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99430153; called by muse, mutect2, varscan2
- S100A14 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100275333, COSV59884862; called by muse, mutect2, varscan2
- SAAL1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.109); catalogued as COSV100253994; called by muse, mutect2, varscan2
- SARDH | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.562); catalogued as COSV100061081; called by muse, mutect2
- SATB2 | c.1661T>C p.V554A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99612175; called by muse, mutect2, varscan2
- SBF2 | c.4390C>T p.Q1464* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99815190; called by muse, mutect2, varscan2
- SCN1A | c.1966G>T p.G656* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as rs1553544555, COSV100321378; called by muse, mutect2
- SCN2A | c.2963C>T p.S988F | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99332844; called by muse, mutect2, varscan2
- SCUBE2 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100496859, COSV100496860; called by muse, mutect2, varscan2
- SDK1 | c.4873G>T p.A1625S | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as COSV101269665; called by muse, mutect2, varscan2
- SELENOT | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs1287391447, COSV72000636; called by muse, mutect2, varscan2
- SETD5 | c.4087C>T p.Q1363* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100200964, COSV56715422; called by muse, mutect2, varscan2
- SHISAL1 | c.574A>T p.M192L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV101151934; called by muse, mutect2, varscan2
- SHISAL1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1312405074, COSV101151940; called by muse, mutect2, varscan2
- SLC16A14 | c.1446G>C p.M482I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99725781; called by muse, mutect2, varscan2
- SLC22A4 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV99569529; called by muse, mutect2
- SLC25A18 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs749900100, COSV99494405; called by muse, mutect2, varscan2
- SLC4A9 | c.1955G>A p.R652H (on ENST00000507527 / NM_001258428.2; = p.R628H on NM_031467.3) | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs774340828, COSV50189473; called by muse, mutect2, varscan2
- SLC6A14 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100903200; called by muse, mutect2, varscan2
- SLTM | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99989347; called by muse, mutect2, varscan2
- SMC4 | c.1853G>T p.R618I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100644103; called by muse, mutect2
- SMG1 | c.4533C>G p.F1511L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV101246645; called by muse, mutect2, varscan2
- SMTN | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60779917; called by muse, mutect2, varscan2
- SNRPA | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99698921; called by muse, mutect2, varscan2
- SPAG4 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV100958327; called by muse, varscan2
- SPC24 | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV70607061, COSV70607286; called by muse, mutect2
- SPINDOC | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.125); catalogued as rs757354424, COSV99588750; called by muse, mutect2
- SSBP4 | c.751-1G>C p.X251_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as rs1314257614, COSV99526258; called by muse, mutect2, varscan2
- SSPN | c.363G>C p.M121I | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV99658796; called by muse, mutect2, varscan2
- STAB2 | c.5545G>A p.D1849N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV101186185; called by muse, mutect2
- STAMBP | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs770534220, COSV100277766; called by muse, mutect2, varscan2
- STAT4 | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.797); catalogued as COSV61829957; called by muse, mutect2, varscan2
- STEAP4 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV57331625; called by muse, mutect2, varscan2
- SUMF2 | c.559G>A p.E187K (on ENST00000652303; = p.E168K on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99305359; called by muse, mutect2
- SUPT16H | c.2196G>C p.K732N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV99360097; called by muse, mutect2, varscan2
- SUPT6H | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.67); catalogued as COSV100112651; called by muse, mutect2, varscan2
- SVEP1 | c.8018C>T p.S2673L | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99929025, COSV99929513; called by muse, mutect2, varscan2
- SVIL | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100881449; called by muse, mutect2, varscan2
- SVOP | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100139538; called by muse, mutect2, varscan2
- TAF7L | c.903G>C p.L301F | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100229615; called by muse, mutect2, varscan2
- TANC1 | c.5441C>T p.S1814F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV99714806; called by muse, mutect2, varscan2
- TAOK2 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99665153; called by muse, mutect2, varscan2
- TBC1D20 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100830588; called by muse, mutect2, varscan2
- TBC1D31 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs1212252138, COSV99783066; called by muse, mutect2, varscan2
- TBC1D31 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99783067; called by muse, mutect2, varscan2
- TEX35 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV99274804; called by muse, mutect2, varscan2
- TGFBR2 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV55447425, COSV99846750; called by muse, mutect2, varscan2
- THAP12 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV99473178; called by muse, mutect2, varscan2
- THOC2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV99833905; called by muse, mutect2, varscan2
- TICRR | c.2164C>G p.Q722E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99178823; called by muse, mutect2, varscan2
- TIGD4 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.867); catalogued as COSV58549768; called by muse, mutect2, varscan2
- TMEM108 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV58864217, COSV58866121, COSV58870157; called by muse, mutect2, varscan2
- TMEM140 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV99313268; called by muse, mutect2, varscan2
- TMEM45B | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV99859494; called by muse, mutect2, varscan2
- TNK2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV100361566; called by muse, mutect2, varscan2
- TNK2 | c.1816C>G p.Q606E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100361572; called by muse, mutect2, varscan2
- TOPORS | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV100859567; called by muse, mutect2, varscan2
- TRANK1 | c.3478G>C p.E1160Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100084127; called by muse, mutect2
- TRIM39 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100935883; called by muse, mutect2, varscan2
- TRIP11 | c.3733G>C p.E1245Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99970989; called by muse, mutect2, varscan2
- TRIP11 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99970990; called by muse, mutect2, varscan2
- TRIP11 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV99970992; called by muse, mutect2, varscan2
- TRIP11 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1194229886, COSV99971000; called by muse, varscan2
- TRIP11 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99971005; called by muse, varscan2
- TRIP11 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs201247031; called by muse, mutect2, varscan2
- TRPC1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99859174; called by muse, mutect2, varscan2
- TRPM1 | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.358); catalogued as COSV99856403; called by muse, mutect2, varscan2
- TSPYL5 | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100439076; called by muse, mutect2, varscan2
- TSSK6 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1568355747, COSV53065508; called by muse, mutect2, varscan2
- TTL | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs745710997, COSV99271497; called by muse, varscan2
- TTN | c.97477G>A p.E32493K (on ENST00000591111; = p.E25069K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | PolyPhen possibly damaging (0.57); catalogued as COSV59862825; called by muse, mutect2, varscan2
- TTN | c.37574C>T p.S12525F (on ENST00000591111; = p.S5101F on NM_003319.4) | Missense Mutation (SNP) | VAF 71/231 reads (31%) | PolyPhen probably damaging (0.98); catalogued as COSV100623538; called by muse, mutect2, varscan2
- TUBA8 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV100283170; called by muse, varscan2
- TUBA8 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV57813841; called by muse, varscan2
- TWIST1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1240371620, COSV54251141, COSV99643138; called by muse, mutect2, varscan2
- UACA | c.3485C>G p.S1162C | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100537642; called by muse, mutect2, varscan2
- UBQLN1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1210145800, COSV99973501; called by muse, mutect2, varscan2
- UHMK1 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99966335; called by muse, mutect2, varscan2
- UNC5D | c.2174C>G p.S725* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99777675; called by muse, mutect2, varscan2
- UNC79 | c.2091C>G p.I697M (on ENST00000393151 / NM_001346218.2; = p.I520M on NM_020818.5) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99829260; called by muse, mutect2, varscan2
- UPB1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144135211, CM123543; called by muse, mutect2, varscan2
- UPRT | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100975847; called by muse, mutect2, varscan2
- USF2 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs1184627505, COSV99723468; called by muse, mutect2, varscan2
- USP35 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs768195133, COSV101489121; called by muse, mutect2
- USP9X | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100199896; called by muse, mutect2, varscan2
- USPL1 | c.2501C>T p.S834L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs554838153, COSV99687504; called by muse, mutect2, varscan2
- VEPH1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100747861; called by muse, mutect2, varscan2
- VPS13B | c.10486G>A p.E3496K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100662951; called by muse, mutect2, varscan2
- VPS13C | c.5672C>T p.S1891L (on ENST00000644861 / NM_020821.3; = p.S1848L on NM_017684.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs777427916, COSV99829662; called by muse, mutect2, varscan2
- VPS33A | c.70C>A p.R24S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99931488; called by muse, mutect2, varscan2
- VPS35L | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99221426; called by muse, mutect2, varscan2
- WDFY3 | c.5873C>G p.A1958G | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV55693578, COSV99884915; called by muse, mutect2, varscan2
- WDHD1 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.698); catalogued as rs1390023355, COSV100864430; called by muse, mutect2, varscan2
- WDR3 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV100832284; called by muse, mutect2
- WDR31 | c.636C>T p.L212= (on ENST00000374193 / NM_001006615.3; = p.L211= on NM_145241.5) | Splice Region (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100516758; called by muse, mutect2, varscan2
- WDR35 | c.3148A>T p.K1050* (on ENST00000345530 / NM_001006657.2; = p.K1039* on NM_020779.4) | Nonsense Mutation (SNP) | VAF 32/220 reads (15%) | catalogued as COSV99853409; called by muse, varscan2
- WDR35 | c.3146T>C p.L1049P (on ENST00000345530 / NM_001006657.2; = p.L1038P on NM_020779.4) | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99853411; called by muse, varscan2
- WNK4 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519533; called by muse, mutect2, varscan2
- XAF1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100695147; called by muse, mutect2, varscan2
- XIRP1 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100453836; called by muse, mutect2, varscan2
- YTHDC2 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99363698; called by muse, mutect2, varscan2
- YTHDC2 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50736529, COSV99363700; called by muse, mutect2, varscan2
- YTHDC2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99363702; called by muse, mutect2, varscan2
- ZBTB24 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100018668; called by muse, mutect2, varscan2
- ZC3H12C | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99585225; called by muse, mutect2
- ZFP2 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100797102; called by muse, mutect2, varscan2
- ZNF10 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV50212776; called by muse, mutect2, varscan2
- ZNF383 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as rs781461790, COSV100776784; called by muse, mutect2, varscan2
- ZNF474 | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99682256; called by muse, mutect2, varscan2
- ZNF546 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.766); catalogued as COSV100713523; called by muse, mutect2, varscan2
- ZNF572 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100074075; called by muse, mutect2, varscan2
- ZNF584 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59723054; called by muse, mutect2, varscan2
- ZNF608 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100102236; called by muse, mutect2, varscan2
- ZNF671 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as COSV100235203; called by muse, mutect2
- ZNF76 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV99987847; called by muse, mutect2
- ZNF784 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs755507259, COSV100323252; called by muse, mutect2, varscan2
- ZNF816 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.468); catalogued as COSV99063861; called by muse, mutect2, varscan2
- ZNRF3 | c.1760G>A p.R587H (on ENST00000544604 / NM_001206998.2; = p.R487H on NM_032173.3) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100238799, COSV60436131; called by muse, mutect2, varscan2
- C6 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- CGB8 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ENAM | c.1244_1267del p.T415_P422del | In Frame Del (DEL) | VAF 24/112 reads (21%) | called by mutect2, pindel
- GPR179 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PNRC2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PNRC2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UHRF1BP1 | c.4040dup p.M1347Ifs*10 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- ZNF107 | c.2247dup p.C750Mfs*18 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ZNF750 | c.152del p.N51Tfs*5 | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | called by mutect2, pindel, varscan2
- ABAT | c.1467C>A p.L489= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99191010; called by muse, mutect2, varscan2
- ABCB5 | c.2283G>T p.G761= (on ENST00000404938 / NM_001163941.2; = p.G316= on NM_178559.6) | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99329149; called by muse, mutect2, varscan2
- ADAMTS2 | c.2892C>T p.P964= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs546361762, COSV52382771; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ALG11 | c.177G>A p.G59= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV101584376; called by muse, mutect2, varscan2
- ALPK3 | c.4518G>A p.L1506= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99361679; called by muse, mutect2, varscan2
- ANKZF1 | c.2180G>A p.*727= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55476806, COSV99850785; called by muse, mutect2, varscan2
- AP2M1 | c.1098C>T p.I366= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99490825; called by muse, mutect2, varscan2
- ARAP1 | c.2685C>T p.F895= (on ENST00000393609 / NM_001040118.2; = p.F650= on NM_015242.4) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100502095; called by muse, mutect2
- ARHGAP44 | c.417G>A p.R139= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99311281; called by muse, mutect2
- ARMC2 | c.2226C>T p.L742= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100933633; called by muse, mutect2, varscan2
- ATMIN | c.2235C>G p.V745= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100214734; called by muse, mutect2
- ATPAF2 | c.846C>G p.V282= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100572790; called by muse, mutect2, varscan2
- B3GALT2 | c.444G>A p.E148= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100813627; called by muse, mutect2, varscan2
- BCAN | c.1221C>T p.S407= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100228350; called by muse, mutect2
- BDP1 | c.1542G>A p.K514= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1303076475, COSV100703383; called by muse, mutect2, varscan2
- BNIP5 | c.1958G>A p.*653= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs370838422; called by muse, mutect2, varscan2
- BOP1 | c.1317C>G p.L439= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- BSN | c.11775C>T p.F3925= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV99609414; called by muse, mutect2, varscan2
- BTBD1 | c.1221C>T p.F407= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99915631; called by muse, mutect2, varscan2
- BTBD6 | c.528C>T p.V176= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100527604; called by muse, mutect2
- C12orf57 | c.282G>A p.E94= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99980822; called by muse, mutect2, varscan2
- C16orf89 | c.273C>T p.R91= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs748814196, COSV60127097; called by muse, mutect2, varscan2
- C1RL | c.156G>A p.L52= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV99864875; called by muse, mutect2, varscan2
- C1orf159 | c.876G>A p.E292= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99618751; called by muse, mutect2
- CAD | c.5643G>A p.L1881= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as rs998353257, COSV99255473; called by muse, mutect2, varscan2
- CC2D1A | c.144C>T p.F48= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV58786134; called by muse, mutect2, varscan2
- CCDC80 | c.348G>A p.E116= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs1187140956, COSV99245119; called by muse, mutect2, varscan2
- CCNG2 | c.69C>G p.V23= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100313321; called by muse, mutect2, varscan2
- CDH24 | c.747C>G p.L249= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99400107; called by muse, mutect2, varscan2
- CFP | c.1020C>T p.I340= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99901610; called by muse, mutect2, varscan2
- COPB1 | c.2298G>A p.L766= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1423703996, COSV99999811; called by muse, mutect2, varscan2
- CRELD1 | c.432C>T p.P144= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs750003238, COSV55972209; called by muse, mutect2, varscan2
- CXCR2 | c.886C>T p.L296= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs760182360, COSV100579069; called by muse, mutect2, varscan2
- CYP11B1 | c.78G>C p.T26= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs147788769, COSV99455510; called by muse, mutect2, varscan2
- CYP2F1 | c.1113C>T p.V371= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100462888; called by muse, mutect2, varscan2
- DDI2 | c.1191G>A p.Q397= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100197837; called by muse, mutect2, varscan2
- DNAH10 | c.3336C>G p.L1112= (on ENST00000409039; = p.L1051= on NM_207437.3) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV101292479; called by muse, mutect2, varscan2
- DNAH11 | c.2793G>A p.L931= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100180148; called by muse, mutect2, varscan2
- DNAH17 | c.9846C>T p.I3282= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV101103082, COSV67760557; called by muse, mutect2, varscan2
- DNTTIP2 | c.1992G>A p.L664= | Silent (SNP) | VAF 72/229 reads (31%) | catalogued as COSV100785197; called by muse, mutect2, varscan2
- EPYC | c.811C>T p.L271= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99664830; called by muse, mutect2
- ESR2 | c.444C>T p.F148= | Silent (SNP) | VAF 41/240 reads (17%) | catalogued as COSV99963658; called by muse, mutect2, varscan2
- ESRRG | c.360C>T p.L120= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV100753601; called by muse, mutect2, varscan2
- EVPL | c.558G>A p.Q186= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1236842680, COSV101648793; called by muse, mutect2
- F11R | c.282C>T p.I94= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs899023730, COSV57037488, COSV57037537; called by muse, mutect2, varscan2
- FAM151A | c.276C>A p.V92= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100157038; called by muse, mutect2, varscan2
- FCGR2A | c.243C>G p.L81= (on ENST00000271450 / NM_001136219.3; = p.L80= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99615600; called by muse, mutect2, varscan2
- FNIP2 | c.2892C>T p.T964= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs781111132, COSV100033120, COSV52440649; called by muse, mutect2, varscan2
- G6PD | c.1530G>T p.V510= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100855082; called by muse, mutect2, varscan2
- GALNT10 | c.768G>A p.R256= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as COSV99769634; called by muse, mutect2, varscan2
- GPATCH8 | c.4006C>T p.L1336= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs753739830, COSV100132786; called by muse, mutect2, varscan2
- GPR160 | c.267C>T p.F89= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100576154; called by muse, mutect2
- GPSM2 | c.1350G>A p.L450= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs963843637, COSV99915498; called by muse, mutect2, varscan2
- GRAMD2A | c.354C>A p.L118= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100550977; called by muse, mutect2, varscan2
- HGSNAT | c.1443G>A p.V481= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV99925416; called by muse, mutect2, varscan2
- HOMER2 | c.966G>A p.L322= (on ENST00000304231 / NM_199330.3; = p.L311= on NM_004839.4) | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV100420486; called by muse, mutect2, varscan2
- HTR2A | c.427C>T p.L143= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV101096779; called by muse, mutect2
- IGF1R | c.1923G>C p.L641= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs529006369, COSV51286452; called by muse, mutect2, varscan2
- IGKV1-17 | c.285C>T p.L95= | Silent (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- IMPA2 | c.633C>T p.L211= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as COSV99302703; called by muse, mutect2, varscan2
- ITPRID2 | c.453G>A p.G151= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100238589; called by muse, mutect2, varscan2
- KIAA1549 | c.966C>T p.Y322= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs984197732, COSV99651583; called by muse, mutect2, varscan2
- KIAA1549L | c.1941G>A p.L647= (on ENST00000321505; = p.L944= on NM_012194.3) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99682486, COSV99684113; called by muse, mutect2, varscan2
- KIR2DL1 | c.780C>T p.L260= | Silent (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- KLB | c.1893G>A p.L631= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs1220812968, COSV57300076; called by muse, mutect2, varscan2
- KLHL3 | c.180G>A p.E60= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV100553447; called by muse, mutect2, varscan2
- KLK4 | c.705T>G p.G235= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV100133682; called by muse, mutect2, varscan2
- KRTAP10-1 | c.816C>T p.L272= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1269496301, COSV100554903; called by muse, mutect2, varscan2
- KRTAP27-1 | c.501C>T p.N167= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV101239752; called by muse, mutect2, varscan2
- LRRC41 | c.2052G>A p.E684= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as COSV100586521; called by muse, mutect2, varscan2
- LRRC8A | c.2337C>G p.L779= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99396811; called by mutect2, varscan2
- MAMDC4 | c.1215G>A p.Q405= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs773469370, COSV99915817; called by muse, mutect2, varscan2
- MBD3 | c.219G>A p.K73= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs777419010, COSV99337051; called by muse, mutect2, varscan2
- MCM7 | c.612C>T p.I204= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV100385086; called by muse, mutect2, varscan2
- MDN1 | c.9936G>A p.K3312= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV65529442; called by muse, varscan2
- MED16 | c.1785C>G p.V595= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1237237923, COSV99516098; called by muse, mutect2, varscan2
- MUC16 | c.38892G>A p.R12964= | Silent (SNP) | VAF 52/217 reads (24%) | catalogued as rs1163025932, COSV67474071; called by muse, mutect2, varscan2
- MYLIP | c.351G>T p.V117= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100786002; called by muse, mutect2, varscan2
- MYRF | c.2733C>T p.S911= (on ENST00000278836 / NM_001127392.3; = p.S876= on NM_013279.4) | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99607596; called by muse, mutect2, varscan2
- NAB2 | c.162C>A p.L54= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV100272740; called by muse, mutect2, varscan2
- NACA | c.597G>A p.L199= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV100771513; called by muse, varscan2
- NACA | c.231G>T p.R77= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100771518; called by muse, mutect2, varscan2
- NFATC2 | c.240C>T p.G80= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs745343071, COSV65355069; called by muse, mutect2, varscan2
- NOTUM | c.537C>T p.F179= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs530981918, COSV101293759; called by muse, mutect2, varscan2
- NPC1L1 | c.1086G>A p.P362= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs201987651; called by muse, varscan2
- NPR1 | c.2427C>T p.S809= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV100902059; called by muse, mutect2, varscan2
- NR1I3 | c.972G>C p.R324= (on ENST00000367982 / NM_001077480.3; = p.R320= on NM_005122.5) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100915821; called by muse, mutect2, varscan2
- NRXN3 | c.2646G>A p.L882= (on ENST00000335750 / NM_001330195.2; = p.L509= on NM_004796.6) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100207110; called by muse, mutect2, varscan2
- NSD3 | c.2535C>T p.L845= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV100395559; called by muse, mutect2, varscan2
- NUDT19 | c.333G>A p.K111= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV101229245; called by muse, mutect2, varscan2
- OR10G4 | c.657C>A p.S219= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV100304924, COSV57977188; called by muse, mutect2, varscan2
- OR2C3 | c.858G>C p.L286= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100825760; called by muse, mutect2
- OR5H15 | c.342C>G p.L114= | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as COSV100736734; called by muse, mutect2, varscan2
- OR6C6 | c.459C>T p.I153= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1251164975, COSV64455446; called by muse, mutect2, varscan2
- PGAP3 | c.270C>T p.F90= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs907183412, COSV100328655; called by muse, mutect2, varscan2
- PI4KA | c.2868G>A p.K956= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV99747806; called by muse, mutect2, varscan2
- PKDREJ | c.1389C>T p.I463= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs759161297, COSV99479311; called by muse, mutect2
- PLCH1 | c.3342G>A p.E1114= (on ENST00000340059 / NM_001130960.2; = p.E1106= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV100396434; called by muse, mutect2, varscan2
- PLEC | c.12651G>A p.L4217= (on ENST00000322810 / NM_201380.4; = p.L4107= on NM_000445.5) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100517293; called by muse, mutect2, varscan2
- PRND | c.51C>G p.L17= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV59896757; called by muse, mutect2, varscan2
- PRPF40B | c.1755C>T p.V585= (on ENST00000380281; = p.V572= on NM_012272.3) | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV99526760; called by muse, mutect2, varscan2
- PTCH2 | c.837G>C p.L279= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100942206; called by muse, mutect2, varscan2
- PYCARD | c.69C>T p.F23= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99910955; called by muse, mutect2, varscan2
- R3HDM1 | c.1461C>T p.I487= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99926578; called by muse, mutect2, varscan2
- RASD1 | c.522C>T p.F174= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99245861; called by muse, mutect2
- RFPL2 | c.666G>A p.E222= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV99964452; called by muse, mutect2
- RNF17 | c.247A>C p.R83= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99694052; called by muse, mutect2, varscan2
- RNF213 | c.14427C>T p.I4809= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100301204; called by muse, mutect2, varscan2
- RPLP0 | c.675C>G p.V225= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV56105496, COSV99935432; called by muse, mutect2, varscan2
- RTEL1 | c.639G>C p.R213= | Silent (SNP) | VAF 65/224 reads (29%) | catalogued as COSV100542667; called by muse, mutect2, varscan2
- RTTN | c.2928C>T p.F976= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99733382; called by muse, mutect2, varscan2
- S100A16 | c.87C>G p.V29= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100905895; called by muse, mutect2, varscan2
- SDC4 | c.153C>T p.P51= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs750999803, COSV101023430, COSV65595392; called by muse, mutect2, varscan2
- SHISAL1 | c.573G>A p.L191= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV101151936; called by muse, mutect2, varscan2
- SLC1A3 | c.1575G>A p.L525= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as rs1289029296, COSV54316946; called by muse, mutect2, varscan2
- SLC22A15 | c.1071G>A p.L357= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV101047353; called by muse, mutect2, varscan2
- SLC41A1 | c.150G>C p.V50= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs775927182, COSV100900456; called by muse, mutect2
- SLC6A7 | c.285C>G p.L95= | Silent (SNP) | VAF 43/170 reads (25%) | catalogued as COSV100046465, COSV57937234; called by muse, mutect2, varscan2
- SLC9A7 | c.1905G>C p.L635= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100092574; called by muse, mutect2, varscan2
- SLCO1B1 | c.1419C>G p.V473= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV99918884; called by muse, mutect2, varscan2
- SPIRE2 | c.1707G>T p.G569= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100988939; called by muse, mutect2, varscan2
- SPON1 | c.1584G>A p.V528= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100116448; called by muse, mutect2
- STARD13 | c.1521C>A p.V507= (on ENST00000336934 / NM_001243476.3; = p.V389= on NM_052851.3) | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV99716229; called by muse, mutect2, varscan2
- STAT2 | c.1770G>T p.L590= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV100029072; called by muse, mutect2
- TAF6 | c.471G>A p.Q157= | Silent (SNP) | VAF 81/292 reads (28%) | catalogued as rs1209209695, COSV59842567; called by muse, mutect2, varscan2
- TANGO6 | c.2265C>A p.A755= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as COSV99936757; called by muse, mutect2
- THAP1 | c.573C>T p.D191= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs758882685, COSV54272998; called by muse, mutect2, varscan2
- TMC2 | c.798T>A p.L266= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100727833; called by muse, mutect2
- TMEM147 | c.423C>T p.I141= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV99382917; called by muse, varscan2
- TMEM198 | c.681C>T p.L227= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs925406073, COSV99525308; called by muse, mutect2
- TMEM44 | c.1335G>C p.V445= (on ENST00000392432 / NM_001166305.2; = p.V408= on NM_138399.5) | Silent (SNP) | VAF 12/276 reads (4%) | catalogued as COSV99861935; called by muse, mutect2
- TMEM53 | c.249C>A p.I83= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100698880; called by muse, mutect2, varscan2
- TNFRSF10B | c.501C>A p.V167= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV99375543; called by muse, mutect2, varscan2
- TNIP3 | c.309G>A p.Q103= | Silent (SNP) | VAF 121/429 reads (28%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.4659C>T p.P1553= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs933096565, COSV100836174; called by muse, mutect2, varscan2
- TP53INP1 | c.705G>A p.P235= | Silent (SNP) | VAF 56/174 reads (32%) | catalogued as rs756928155, COSV100711122; called by muse, mutect2, varscan2
- TRIP11 | c.3189G>A p.Q1063= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99970993; called by muse, varscan2
- TRRAP | c.4641G>C p.L1547= (on ENST00000359863 / NM_001244580.1; = p.L1529= on NM_003496.3) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100722757; called by muse, mutect2, varscan2
- TUBGCP5 | c.1234C>T p.L412= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- VIRMA | c.4317A>G p.K1439= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1477520513, COSV99889028; called by muse, mutect2, varscan2
- VSTM2L | c.441C>T p.F147= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100991698; called by muse, mutect2, varscan2
- WDR35 | c.3147G>A p.L1049= (on ENST00000345530 / NM_001006657.2; = p.L1038= on NM_020779.4) | Silent (SNP) | VAF 30/221 reads (14%) | catalogued as COSV55604339; called by muse, varscan2
- XKR3 | c.213C>T p.I71= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100509341; called by muse, mutect2, varscan2
- YTHDC2 | c.1827C>T p.I609= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99362952, COSV99363704; called by muse, mutect2, varscan2
- YY1 | c.1161C>T p.F387= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs1566782832, COSV99216939; called by muse, mutect2, varscan2
- ZCCHC8 | c.1572G>A p.Q524= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as rs757213035, COSV100288780, COSV60317013; called by muse, mutect2, varscan2
- ZIC5 | c.1506C>T p.F502= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV57439169; called by muse, mutect2, varscan2
- ZNF19 | c.267C>T p.V89= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99867605; called by muse, mutect2, varscan2
- ZNF354C | c.1599C>T p.F533= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV100203546, COSV59607212; called by muse, mutect2, varscan2
- ZNF70 | c.1267C>T p.L423= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as COSV100558921; called by muse, mutect2, varscan2
- ZNF70 | c.552C>G p.L184= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100558922; called by muse, mutect2, varscan2
- ZNF700 | c.1635C>T p.F545= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99583717; called by muse, varscan2
- ZNF766 | c.840C>T p.F280= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100765409; called by muse, mutect2, varscan2
- ZZEF1 | c.1344C>G p.L448= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV101067952; called by muse, mutect2, varscan2
- ADD2 | c.1742-268C>T | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100036210; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504334 G>C | 5'Flank (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504637 G>A | 5'Flank (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505009 G>A | 5'Flank (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- AP000769.3 | chr11:65505085 G>A | 5'Flank (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505208 G>A | 5'Flank (SNP) | VAF 14/56 reads (25%) | catalogued as rs370181065; called by muse, varscan2
- AP000769.3 | chr11:65505284 G>T | 5'Flank (SNP) | VAF 9/43 reads (21%) | catalogued as rs772817101; called by muse, varscan2
- AP000769.3 | chr11:65505361 G>A | 5'Flank (SNP) | VAF 5/36 reads (14%) | catalogued as rs756975149; called by muse, varscan2
- AP000769.3 | chr11:65505610 G>A | 5'Flank (SNP) | VAF 24/116 reads (21%) | catalogued as rs748797375; called by muse, varscan2
- ASPSCR1 | c.1354-1244C>G | Intron (SNP) | VAF 21/114 reads (18%) | catalogued as COSV100142440; called by muse, mutect2, varscan2
- ATP13A4 | c.-1C>T | 5'UTR (SNP) | VAF 33/417 reads (8%) | catalogued as rs143808160, COSV99795050; called by muse, mutect2
- CABP1 | c.655-3776G>C | Intron (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99974797; called by muse, mutect2, varscan2
- CDKN1B | c.*105C>A | 3'UTR (SNP) | VAF 6/27 reads (22%) | catalogued as COSV57429906; called by muse, mutect2, varscan2
- DCHS2 | n.758G>C | RNA (SNP) | VAF 30/134 reads (22%) | catalogued as COSV100252701; called by muse, mutect2, varscan2
- GDF5 | c.-398+652G>C | Intron (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100699090; called by muse, mutect2
- NACA | c.71-1719G>C | Intron (SNP) | VAF 91/387 reads (24%) | catalogued as COSV63270133; called by muse, mutect2, varscan2
- NACA | c.71-2009G>A | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100771522; called by muse, varscan2
- NACA | c.71-2163G>C | Intron (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100771528; called by muse, varscan2
- NACA | c.71-3008G>C | Intron (SNP) | VAF 29/111 reads (26%) | catalogued as COSV100771529; called by muse, mutect2, varscan2
- NACA | c.71-3709G>A | Intron (SNP) | VAF 33/75 reads (44%) | catalogued as COSV100771530; called by muse, mutect2, varscan2
- NACA | c.71-3988G>A | Intron (SNP) | VAF 19/75 reads (25%) | catalogued as COSV63273636; called by muse, mutect2, varscan2
- NACA | c.71-4526G>T | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100771531; called by muse, mutect2, varscan2
- OGFOD3 | c.824-1972A>T | Intron (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100234518; called by muse, mutect2, varscan2
- RUFY3 | chr4:70794836 G>A | 3'Flank (SNP) | VAF 6/103 reads (6%) | catalogued as COSV99887712; called by muse, mutect2
- RUFY3 | chr4:70794837 A>T | 3'Flank (SNP) | VAF 6/104 reads (6%) | catalogued as COSV99887713; called by muse, mutect2
- SLC35D3 | c.-1G>A | 5'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as rs1294344536, COSV100090521, COSV100090659; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1313G>A | RNA (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
